Somatic mutation profile of cancer-model specimen HCM-CSHL-0853-C56-85F (3D Organoid, passage 7; aliquot HCM-CSHL-0853-C56-85F-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-85F: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fa24959-b0ef-4385-9340-fbcc1a60a437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0853-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0853-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dce1d0a-1df9-42e2-94d4-cd6e05e52318

The open-access MAF lists 66 somatic variants for this specimen: 41 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 24, 5'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 205/234 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGTPBP1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 87/405 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.946); catalogued as rs201090962, COSV100429851; called by muse, mutect2, varscan2
- APOBR | c.1081G>T p.D361Y (on ENST00000431282; = p.D370Y on NM_018690.4) | Missense Mutation (SNP) | VAF 157/269 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1009328585; called by muse, varscan2
- C2CD2L | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 98/859 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as rs940210543; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 219/246 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CNOT1 | c.4196G>A p.R1399Q | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55320287; called by muse, mutect2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- DOCK8 | c.6136C>A p.L2046I | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs747086561; called by muse, mutect2
- FAM160A2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 163/469 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768160220; called by muse, mutect2, varscan2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 113/282 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- GRIN2D | c.1576G>C p.G526R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54381923; called by muse, mutect2, varscan2
- OR5R1 | c.567C>G p.C189W | Missense Mutation (SNP) | VAF 133/413 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100393585; called by muse, mutect2, varscan2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/393 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- TMEM175 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 69/418 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs577438263, COSV53279397; called by muse, varscan2
- TTL | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51973743; called by muse, mutect2, varscan2
- UNC5D | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 47/539 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs568619133; called by muse, mutect2
- ZNF461 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV64454997; called by muse, mutect2, varscan2
- BEST2 | c.181T>A p.Y61N | Missense Mutation (SNP) | VAF 60/712 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2
- CAPZA1 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 106/367 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CETP | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- CKMT1A | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 90/388 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2
- CSPG4 | c.2564G>T p.G855V | Missense Mutation (SNP) | VAF 44/733 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2
- CSPG4 | c.2563G>C p.G855R | Missense Mutation (SNP) | VAF 44/736 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.843); called by muse, mutect2
- EFEMP2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 120/396 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FBN3 | c.6535T>A p.F2179I | Missense Mutation (SNP) | VAF 101/319 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRRS1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GRSF1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 167/395 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GYS1 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 126/188 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ITIH4 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 126/136 reads (93%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MMAA | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MUC16 | c.33677C>T p.T11226I | Missense Mutation (SNP) | VAF 20/544 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- NDUFS4 | c.422dup p.N141Kfs*6 | Frame Shift Ins (INS) | VAF 17/110 reads (15%) | called by mutect2, varscan2
- NRXN1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 97/313 reads (31%) | called by muse, mutect2, varscan2
- ORAI1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 141/498 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, varscan2
- PHLDA2 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 332/906 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PRSS36 | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 328/374 reads (88%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RCN3 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SGPL1 | c.876_877del p.H292Qfs*8 | Frame Shift Del (DEL) | VAF 114/485 reads (24%) | called by mutect2, pindel, varscan2
- SPATA18 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 168/343 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TRPA1 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13B | c.3499C>G p.L1167V | Missense Mutation (SNP) | VAF 96/765 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAM20 | c.507A>C p.P169= | Silent (SNP) | VAF 105/337 reads (31%) | called by muse, mutect2, varscan2
- AP3B1 | c.1932C>T p.P644= | Silent (SNP) | VAF 82/90 reads (91%) | catalogued as rs368771979; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1146G>A p.K382= | Silent (SNP) | VAF 24/750 reads (3%) | catalogued as rs1047612129; called by muse, mutect2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 119/287 reads (41%) | called by muse, mutect2, varscan2
- BACE1 | c.534C>T p.G178= | Silent (SNP) | VAF 32/496 reads (6%) | catalogued as rs755703640; called by muse, mutect2
- CATSPER2 | c.711C>T p.A237= | Silent (SNP) | VAF 20/259 reads (8%) | catalogued as COSV58661491; called by muse, mutect2
- HECTD3 | c.975C>T p.D325= | Silent (SNP) | VAF 21/364 reads (6%) | catalogued as rs1396934023, COSV55801354; called by muse, mutect2
- KIAA1522 | c.777C>A p.T259= (on ENST00000373480 / NM_001198972.2; = p.T318= on NM_020888.3) | Silent (SNP) | VAF 600/1012 reads (59%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.867C>T p.N289= | Silent (SNP) | VAF 287/388 reads (74%) | catalogued as rs374654639; called by muse, mutect2, varscan2
- MUC12 | c.2910T>C p.H970= (on ENST00000379442; = p.H827= on NM_001164462.1) | Silent (SNP) | VAF 116/532 reads (22%) | catalogued as rs1232372270; called by muse, varscan2
- MYOM3 | c.948G>A p.S316= | Silent (SNP) | VAF 132/391 reads (34%) | catalogued as rs764170415, COSV58392651; called by muse, mutect2, varscan2
- NCAPH | c.687C>T p.N229= | Silent (SNP) | VAF 101/322 reads (31%) | catalogued as rs760742546; called by muse, mutect2, varscan2
- NR0B2 | c.138C>T p.P46= | Silent (SNP) | VAF 30/397 reads (8%) | catalogued as rs370821222; called by muse, mutect2
- PPARD | c.960C>T p.L320= | Silent (SNP) | VAF 31/628 reads (5%) | catalogued as rs760315803; called by muse, mutect2
- PXDN | c.480C>T p.L160= | Silent (SNP) | VAF 20/437 reads (5%) | catalogued as rs1320356614; called by muse, mutect2
- RBM25 | c.432C>G p.L144= | Silent (SNP) | VAF 100/353 reads (28%) | called by muse, mutect2, varscan2
- SERINC2 | c.792C>G p.P264= (on ENST00000373709 / NM_178865.5; = p.P268= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/359 reads (29%) | called by muse, mutect2, varscan2
- SHOC1 | c.2052G>A p.L684= | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- SIGIRR | c.747G>A p.L249= | Silent (SNP) | VAF 242/638 reads (38%) | called by muse, mutect2, varscan2
- SKP2 | c.210G>T p.L70= | Silent (SNP) | VAF 176/513 reads (34%) | called by muse, mutect2, varscan2
- SLC6A12 | c.1554C>T p.S518= | Silent (SNP) | VAF 101/270 reads (37%) | called by muse, mutect2, varscan2
- SPAG1 | c.838C>T p.L280= | Silent (SNP) | VAF 71/606 reads (12%) | called by muse, mutect2, varscan2
- TIGD5 | c.9C>T p.P3= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- WDR35 | c.2011C>T p.L671= (on ENST00000345530 / NM_001006657.2; = p.L660= on NM_020779.4) | Silent (SNP) | VAF 162/437 reads (37%) | called by muse, mutect2, varscan2
- HSPB7 | chr1:16019339 del CTGT | 5'Flank (DEL) | VAF 285/668 reads (43%) | called by mutect2, pindel, varscan2
